National Lung Screening Trial (NLST) participant 102045 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 57 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 42): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, display field of view 34 cm, reconstruction filter GE, other.
- T1 (day 386): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, 53 effective mAs, display field of view 34 cm, reconstruction filter GE, other / GE Standard.
- T2: No screening result: Not Compliant - Refused a screen.

Abnormalities recorded by the reading radiologist on the CT screens (6 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 8 mm, longest perpendicular diameter 6 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 51.
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 54.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 8 mm, longest perpendicular diameter 6 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 54; pre-existing on earlier images (earliest visible day 42); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 58; pre-existing on earlier images (earliest visible day 42); no interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Non-calcified hilar/mediastinal adenopathy or mass (>= 10 mm on short axis); new (not pre-existing on earlier images).

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,322.
